CGCI case BLGSP-71-27-00512 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/67bcc4f6-a39b-4cd5-8647-41646026dfa9

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 54 years; Vital status: Alive.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Classification of tumor: primary; Age at diagnosis: 54.3 years (19,825 days); Year of diagnosis: 2017; Method of diagnosis: Excisional Biopsy; Ann Arbor pathologic stage: Stage IV; Ann Arbor B symptoms: Yes; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 247 days; Ann Arbor extranodal involvement: Yes; Max tumor bulk site: Mediastinal lymph nodes; Sites of involvement: Bone marrow / Pancreas, NOS.
   Pathology details: Bone marrow malignant cells: Yes; Lymph node involved site: Mediastinal; Tumor largest dimension diameter: 2.6 cm.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Initial Diagnosis; Regimen or line of therapy: R-CODOX-M; Days to treatment start: 4 days; Days to treatment end: 66 days; Number of cycles: 2; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Initial Diagnosis; Regimen or line of therapy: R-IVAC; Days to treatment start: 4 days; Days to treatment end: 66 days; Number of cycles: 2; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Cytarabine + Doxorubicin + Etoposide + Ifosfamide + Methotrexate + Rituximab + Vincristine; Initial disease status: Initial Diagnosis; Days to treatment start: 4 days; Days to treatment end: 66 days; Number of cycles: 2; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Initial Diagnosis; Regimen or line of therapy: DA-EPOCH; Days to treatment start: 65 days; Days to treatment end: 107 days; Number of cycles: 3; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Doxorubicin + Etoposide + Prednisone + Rituximab + Vincristine; Initial disease status: Initial Diagnosis; Days to treatment start: 65 days; Days to treatment end: 107 days; Number of cycles: 3; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 0 days; Karnofsky performance status: 80; ECOG performance status: 1.
- Days to follow up: 191 days; Disease response: Tumor Free.
- Days to follow up: 247 days; Disease response: Tumor Free.

Molecular and laboratory tests
- ALK (IHC): Negative.
- BCL2 (IHC): Negative.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CCND1 (IHC): Negative.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD23 (IHC): Positive.
- CD3 (IHC): Negative.
- CD3 (IHC): Positive.
- CD30 (IHC): Negative.
- CD34 (IHC): Negative.
- CD5 (IHC): Positive.
- IRF4 (IHC): Positive.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MYC translocation (FISH): Positive.
- Test (IHC): Positive; Specialized molecular test: CD43.
- Lactate Dehydrogenase 2446 [Blood test normal range upper: 250].

Other clinical attributes
- Day 0: Weight: 90.5 kg; Height: 173 cm; BMI: 30.2.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample BLGSP-71-27-00512-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Tissue collection type: Retrospective.
  Slide BLGSP-71-27-00512-01A-01-S2-HE: Section location: Bottom; Percent tumor cells: 65; Percent tumor nuclei: 90; Percent normal cells: 20; Percent necrosis: 5; Percent stromal cells: 10; Percent lymphocyte infiltration: 50; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 5.
  Slide BLGSP-71-27-00512-01A-01-S1-HE: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 85; Percent normal cells: 30; Percent necrosis: 5; Percent stromal cells: 5; Percent lymphocyte infiltration: 50; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 5.
- Sample BLGSP-71-27-00512-01Z: Sample type: Tumor; Tissue type: Tumor.
  Slide BLGSP-71-27-00512-01-HE-1: Tissue microarray coordinates: D1,B3,F4.
  Slide BLGSP-71-27-00512-01-BCL2: Tissue microarray coordinates: D1,B3,F4.
  Slide BLGSP-71-27-00512-01-CD20: Tissue microarray coordinates: D1,B3,F4.
  Slide BLGSP-71-27-00512-01-Ki67: Tissue microarray coordinates: D1,B3,F4.
  Slide BLGSP-71-27-00512-01-CD10: Tissue microarray coordinates: D1,B3,F4.
  Slide BLGSP-71-27-00512-01-BCL6: Tissue microarray coordinates: D1,B3,F4.
  Slide BLGSP-71-27-00512-01-CD3: Tissue microarray coordinates: D1,B3,F4.
- Sample BLGSP-71-27-00512-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen; Days to sample procurement: 86 days; Method of sample procurement: Blood Draw; Tissue collection type: Retrospective.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- Primary pathology: Histologic diagnosis: Burkitt lymphoma (BL), classic morphology; Extranodal site involvement: 2; Lymph nodes examined: No; Bone marrow sample histology: Concordant Histology.
- Primary pathology, Extranodal involvement sites: Extranodal involvement site: Bone Marrow; Extranodal involvement site: Pancreas.
- Stage record, Ann arbor: B symptoms present indicator: Yes.
- Tests performed: LDH level: 2446; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunophenotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 4: Immunophenotypic analysis tested: BCL2.
- Tests performed, Genetic testing results, Genetic testing result 6: Immunophenotypic analysis tested: CD3.
- Tests performed, Genetic testing results, Genetic testing result 7: Immunophenotypic analysis tested: CD43.
- Tests performed, Genetic testing results, Genetic testing result 8: Immunophenotypic analysis tested: MUM1.
- Tests performed, Genetic testing results, Genetic testing result 9: Immunophenotypic analysis tested: cyclin D1.
- Tests performed, Genetic testing results, Genetic testing result 10: Immunophenotypic analysis tested: ALK-1.
- Tests performed, Genetic testing results, Genetic testing result 11: Immunophenotypic analysis tested: CD34.
- Tests performed, Genetic testing results, Genetic testing result 12: Immunophenotypic analysis tested: CD30.
- Tests performed, Genetic testing results, Genetic testing result 13: Immunophenotypic analysis tested: CD5.
- Tests performed, Genetic testing results, Genetic testing result 14: Immunophenotypic analysis tested: CD23.
- Follow-up form: Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Treatments, Treatment 1: Therapy regimen: Initial; Chemo end reporting period: Yes; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharmaceutical regimen other: R-codox-m/r-ivac; Pharma adjuvant cycles count: 2.
- Treatments, Treatment 2: Therapy regimen: Initial; Chemo end reporting period: Yes; Pharmaceutical regimen: DA-EPOCH + Rituxumab; Pharma adjuvant cycles count: 3.
